Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMF, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMF-01A (Primary Tumor).

[page 1 of 7]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

CLCF *ICD-O-3*
path *Carcinoma, urothelial NOS* *8/20/13*
Carcinoma, transitional cell NOS *8/20/13*
Site Bladder NOS *67.9*
W 8/26/14

Document Type:
*Date - Date of Service:
Document Status:
Document Title:
Encounter info:
Contributor System:

* Final Report *

ORDERING PHYSICIAN:

Ordering Physician:

MICROSCOPIC DESCRIPTION:

A-C: See final microscopic-diagnosis.

D: Sections of the bladder show invasive transitional cell carcinoma, grade 4/4 penetrating the muscularis propria extending into the perivesical fat to involve the soft tissue around the posterior prostate and the seminal vesicles. The tumor is composed of sheets of highly malignant cells with high nuclear cytoplasmic ratio. Vascular space invasion is identified. Multiple soft tissue deposits are also identified. No urothelial carcinoma in situ (flat lesion) identified. The prostate parenchyma is free of urothelial carcinoma.

Sections show focal prostatic adenocarcinoma, Gleason's score 6 (3+3) identified in the left apical region, confined to the gland. The prostatic urethra and stroma are free of urothelial dysplasia and carcinoma.

E-U: See final microscopic-diagnosis.

Signature Line

Signed by:

ELECTRONIC SIGNATURE

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right ureter distal." It consists of a 1 x 1 x 0.5 cm section of ureter. Entirely submitted for frozen section.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter." It consists of a 1 x 1 x 0.5 cm segment of ureter. Entirely submitted in one cassette for frozen section.

C: The specimen is received fresh from the O.R. and labeled "Paracaval LN proximal limits of dissection." It consists of a 2.5 x 2 x 0.5 cm portion of greasy yellow tissue containing a few tiny tan lymph nodes. The lymph nodes are submitted for frozen section section in one cassette.

Printed by:
Printed on:

Page 1 of 7
(Continued)

[page 2 of 7]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

D: The specimen is received fresh from the O.R. and labeled "Bladder & Prostate." It consists of a 26 x 13.5 x 6 cm bladder and prostatectomy. The peritoneum measures 6 x 5 cm and shows tumor studding over a 2.2 cm area. The tumor studs are each less than 0.2 cm in greatest dimension and bear a reddish discoloration. The bladder measures 7 x 7 x 4 cm. The prostate measures 6 x 5 x 4 cm. The right distal ureter measures 3 cm in length and 0.5 cm in diameter distally with a circumference of 4 cm proximally. The left distal ureter measures 4 cm in length and 1.9 cm in circumference. The ureteral mucosa is unremarkable. An ulcerated mass measuring 3.5 cm in greatest dimension is located in the posterior bladder wall. The mass is firm and surmounted by necrotic debris. The borders of the ulcerated mass are heaped and erythematous. Serial sectioning reveals a maximal depth of invasion 0.9 cm. The mass is firm and white with geographic areas of necrosis and grossly penetrates the fat. The uninvolved bladder wall is somewhat pliable but appears to be hypertrophy. The non-neoplastic mucosa is unremarkable and there are no polypoid projections. Serial sectioning reveals diffuse nodularity of the lateral lobe of the prostate. The prostatic urethra measures 3.8 cm in length and 4.8 cm in circumference. The verumontanum measures 0.8 x 0.5 x 0.3 cm. The mucosa of the prostatic urethra is unremarkable. Representative sections are submitted in 20 cassettes.

E: The specimen is received in formalin and labeled "Para aortic lymph nodes." It consists of 5 x 3 x 1.5 cm of greasy yellow tissue entirely submitted in two cassettes.

F: The specimen is received in formalin and labeled "Para caval lymph nodes." It consists of 5 x 2.5 x 1 cm of greasy yellow tissue fragment. Entirely submitted in one cassette.

G: The specimen is received in formalin and labeled "Right common iliac lymph nodes." It consists of 4 x 2 x 0.5 cm of greasy yellow tissue fragment. Entirely submitted in one cassette.

H: The specimen is received in formalin and labeled "Left common iliac lymph nodes." It consists of 7.5 x 4.5 x 2 cm of greasy yellow tissue fragment. Entirely submitted in three cassettes.

I: The specimen is received in formalin and labeled "Right LN of cloquet." It consists of 1.5 x 0.8 x 0.4 cm of greasy yellow tissue fragment. Entirely submitted in one cassette.

J: The specimen is received in formalin and labeled "Right external iliac lymph nodes." It consists of 6.5 x 5.5 x 2 cm of greasy yellow tissue. Entirely submitted in four cassettes.

K: The specimen is received in formalin and labeled "Right obturator / hypogastric lymph nodes." It consists of 8 x 5 x 3 cm of greasy yellow tissue fragment. Entirely submitted in five cassettes.

L: The specimen is received in formalin and labeled "Left external iliac lymph nodes." It consists of 7 x 5 x 2 cm of greasy yellow tissue. Two palpable lymph nodes are identified. Entirely submitted in five cassettes.

M: The specimen is received in formalin and labeled "Left LN of cloquet." It consists of 2 x 2 x 0.7 cm of adipose

Printed by:
Printed on:

Page 2 of 7
(Continued)

[page 3 of 7]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

tissue fragment. Representative section in one cassette.

N: The specimen is received in formalin and labeled "Left hypogastric / obturator lymph nodes." It consists of a 9 x 7 x 2.5 cm of greasy yellow tissue fragment. Representative sections are submitted in five cassettes.

O: The specimen is received in formalin and labeled "Right peri rectal soft tissue." It consists of 3.5 x 1.5 x 0.3 cm of greasy yellow tissue. Entirely submitted in one cassette.

P: The specimen is received in formalin and labeled "Left peri rectal soft tissue." It consists of 5.5 x 2.5 x 1 cm of greasy yellow tissue fragment. No lymphadenopathy. Representative sections submitted in one cassette.

Q: The specimen is received in formalin and labeled "Right pre sciatic lymph nodes." It consists of 3.2 x 2.7 x 0.5 cm of greasy yellow tissue and a 3 x 1 x 0.5 cm blood clot. The greasy yellow tissue is submitted in its entirety in one cassette, and blood clot is submitted in cassette Q2.

R: The specimen is received in formalin and labeled "Pre sacral lymph node". It consists of greasy yellow tissue measuring 5.0 x 5.0 x 1.0 cm. The specimen is entirely submitted in four cassettes.

S: The specimen is received in formalin and labeled "Left presciatic LN." It consists of 5 x 2.5 x 0.7 cm of greasy yellow tissue. Entirely submitted in two cassettes.

T: The specimen is received in formalin and labeled "Left proximal ureter." It consists of a 2.5 x 1 x 0.7 cm greasy yellow tissue fragment. Entirely submitted in one cassette.

U: The specimen is received in formalin and labeled "Right proximal ureter." It consists of a 1.2 x 1 x 0.7 cm greasy yellow tissue fragment. Serially sectioned and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, paracaval lymph node proximal limits of dissection
D1,2: maximum depth of invasion
D3: peritoneal studding
D4-6: non-neoplastic mucosa
D7: right ureteral margin
D8: left ureteral margin
D9: right prostatic apex
D10: left prostatic apex
D11: right mid prostate
D12: left mid prostate
D13: right proximal prostate

Printed by:
Printed on:

Page 3 of 7
(Continued)

[page 4 of 7]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

D14: left proximal prostate
D15-19: perivesical fat pad
D20: true peritoneal margin
E1,2: para-aortic lymph nodes
F: paracaval lymph nodes
G: right common iliac lymph nodes
H1-3: left common iliac lymph nodes
I: right lymph node of Cloquet
J1: single lymph node, bisected
J2: single lymph node, bisected
J3,4: remaining tissue
K1: lymph node
K2-5: remaining tissue
L1: first lymph node
L2: second lymph node
L3-5: remaining tissue
M: left lymph node of Cloquet
N1,2: lymph nodes
N3: possible lymph node
N4: lymph nodes
N5: sample of remaining tissue
O: right perirectal soft tissue
P: left perirectal soft tissue
Q1: right presciatic lymph nodes
Q2: blood clot
R1-4: presacral lymph node
S1: lymph node, bisected
S2: remaining tissue
T: left proximal ureter
U: right proximal ureter

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right ureter distal:

- no high grade urothelial atypia or carcinoma identified

BFS: Left distal ureter:

- no high grade urothelial atypia or carcinoma identified

Printed by:

Printed on:

Page 4 of 7
(Continued)

[page 5 of 7]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

CFS: Paracaval lymph node proximal limits of dissection:
- negative

DIAGNOSIS COMMENT:

Section of the tumor (D2) is submitted for p53 analysis and the results will be issued in an addendum to follow.

FINAL DIAGNOSIS:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL ATYPIA OR CARCINOMA IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO HIGH GRADE UROTHELIAL ATYPIA OR CARCINOMA IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL ATYPIA OR CARCINOMA IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO HIGH GRADE UROTHELIAL ATYPIA OR CARCINOMA IDENTIFIED

PARA-AORTIC LYMPH NODES (C):

FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- NO TUMOR IDENTIFIED IN ONE LYMPH NODE (0/1)

URINARY BLADDER AND PROSTATE (D):

BLADDER:

- TRANSITIONAL CELL CARCINOMA, GRADE 4/4, PENETRATING THE MUSCULARIS PROPRIA AND EXTENDING INTO PERIVESICAL FAT TO INVOLVE THE PERIVESICAL FAT AND SOFT TISSUE AROUND THE POSTERIOR PROSTATE AND THE SEMINAL VESICLES
- TUMOR GROSSLY MEASURES 3.5 CM AND IS LOCATED ON POSTERIOR WALL
- VASCULAR SPACE INVASION IDENTIFIED
- SOFT TISSUE TUMOR DEPOSITS ARE IDENTIFIED
- NO UROTHELIAL IN SITU CARCINOMA IDENTIFIED (FLAT LESION)
- THE PROSTATE PARENCHYMA IS FREE OF UROTHELIAL CARCINOMA

Printed by:

Printed on:

Page 5 of 7
(Continued)

[page 6 of 7]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

PROSTATE:

- FOCAL PROSTATIC ADENOCARCINOMA, GLEASON' S SCORE 6 (3+3) IDENTIFIED IN THE LEFT APICAL REGION, CONFINED TO THE GLAND
- NO CAPSULAR INVASION IDENTIFIED
- PROSTATIC URETHRA AND STROMA, FREE OF UROTHELIAL DYSPLASIA OR CARCINOMA

PARA-AORTIC LYMPH NODES (E):

- NO EVIDENCE OF MALIGNANCY IN THREE LYMPH NODES (0/3)

PARACAVAL LYMPH NODES (F):

- NO EVIDENCE OF MALIGNANCY IN FIVE LYMPH NODES (0/5)

RIGHT COMMON ILIAC LYMPH NODES (G):

- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES (0/4)

LEFT COMMON ILIAC LYMPH NODES (H):

- NO EVIDENCE OF MALIGNANCY IN TEN LYMPH NODES (0/10)

RIGHT LYMPH NODE OF CLOQUET (I):

- NO LYMPHOID TISSUE IDENTIFIED
- NO EVIDENCE OF MALIGNANCY

RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- NO EVIDENCE OF MALIGNANCY IN THREE LYMPH NODES (0/3)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (K):

- METASTATIC TRANSITIONAL CELL CARCINOMA IDENTIFIED IN TWO OF 21 LYMPH NODES (2/21)

LEFT EXTERNAL ILIAC LYMPH NODES (L):

- NO EVIDENCE OF MALIGNANCY IN TEN LYMPH NODES (0/10)

LEFT LYMPH NODE OF CLOQUET (M):

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

LEFT HYPOGASTRIC / OBTURATOR LYMPH NODES (N):

- TRANSITIONAL CELL CARCINOMA PRESENT IN SOFT TISSUE WITHOUT ASSOCIATED NODAL TISSUE
- NO EVIDENCE OF MALIGNANCY IN SEVEN LYMPH NODES EXAMINED (0/7)

Printed by:
Printed on:

Page 6 of 7
(Continued)

[page 7 of 7]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

RIGHT PERIRECTAL SOFT TISSUE (O):

- NO LYMPHOID TISSUE IDENTIFIED
- NO EVIDENCE OF MALIGNANCY

LEFT PERIRECTAL SOFT TISSUE (P):

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES (0/2)

RIGHT PRESACRAL LYMPH NODES (Q):

- METASTATIC TRANSITIONAL CELL CARCINOMA IDENTIFIED IN THREE OF FIVE LYMPH NODES (3/5)

LEFT PRESACRAL LYMPH NODES (R):

- NO EVIDENCE OF MALIGNANCY IN SIX LYMPH NODES (0/6)

LEFT PRESACRAL LYMPH NODES (S):

- NO EVIDENCE OF MALIGNANCY IN FIVE LYMPH NODES (0/5)

LEFT PROXIMAL URETER (T):

- BENIGN URETER
- NO HIGH GRADE UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED
- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

RIGHT PROXIMAL URETER (U):

- BENIGN URETER
- NO HIGH GRADE UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED
- PERIURETERAL SOFT TISSUE SHOWS A FOCUS OF TRANSITIONAL CELL CARCINOMA

LYMPH NODE SUMMARY: METASTATIC TRANSITIONAL CELL CARCINOMA IDENTIFIED IN FIVE OUT OF TOTAL OF 83 LYMPH NODES (5/83)

Completed Action List:

Printed by:
Printed on:

Page 7 of 7
(End of Report)

Source: NCI Genomic Data Commons file be692deb-89aa-4f6d-a576-6f64a10a0bb5 (TCGA-XF-AAMF.1F998F05-1055-4BBB-B3CF-BF07C0066A26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).